Gene-level copy-number profile of tumor specimen TCGA-29-2425-01A from TCGA case TCGA-29-2425, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 60.5 years (22,089 days).
Specimen TCGA-29-2425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8c4197c4-c7bd-49e2-8efa-c6c5ea968e69.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-2425-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/754e76e6-69fa-442f-ba57-a759dce2738f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,833; copy number 2: 13,072; copy number 3: 19,210; copy number 4: 14,131; copy number 5: 7,891; copy number 6: 962; copy number 7: 67; copy number 8: 759; copy number 9: 827; copy number 10: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-29-2425-01): tumor purity 0.9, ploidy 3.57, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,720 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,471,119–240,776,824, 49 genes, copy number 7: MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr6:1,623,806–29,292,963, 610 genes, copy number 8–10 (within-gene range 2–10) (broad region; genes not listed).
- chr6:73,693,903–109,878,098, 442 genes, copy number 8–9 (within-gene range 3–9) (broad region; genes not listed).
- chr8:103,500,696–104,256,094, 1 gene, copy number 8 (within-gene range 4–8): RIMS2.
- chr8:103,768,281–145,066,685, 600 genes, copy number 8–9 (broad region; genes not listed).
- chr20:87,250–543,835, 18 genes, copy number 7: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1.

Autosomal genes at a single copy (total copy number 1): 412. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
